Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EW, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EW-01A (Primary Tumor).

[page 1 of 2]
ICD O-3

Melanoma, epithelioid &
spindle cell mixed 8770/3
Site ~~Choroid~~ Choroid C69.3
Uveal tract C69.4

QW 2/16/14

Enucleation of the left eye.

Macroscopy:

The eyeball measures 25 mm in diameter and the posterior optic nerve segment 6 mm. At the section, it presents a pigmented endo-ocular tumor measuring 18 mm main line and 10 mm in thickness at the upper temporal region. Tumor specimens have been taken for cryopreservation then the piece has been fixed and included entirely.

See path discrepancy form for epithelioid and spindle cell ratio.

Microscopy

The tumor observed macroscopically is a cell proliferation presenting the histological features of an uveal melanoma. This tumor is mainly composed of fusiform cells (60%) mixed with a focal component of epithelioid cells (40%). About 10% of the tumor cells are pigmented. The cellular atypias are severe with frequent anisocaryosis and large nucleoli. Presence of mitotic features (ten mitoses per 10 high power field).

The tumor invades the 1/3 inner part of the sclera, without extension to the 2/3 outer part. The optic nerve in its entire course and cut end, the ciliary body, the lamina cribrosa, and the meningeal sheaths are free of tumor.

Conclusion:

Uveal melanoma of mixed type, with a main component of fusiform cells and focal component of epithelioid cells.

Tumor size: 18 mm.

Tumor infiltration of the inner third of the sclera without extra-scleral extension.

Ciliary body, iris, anterior chamber, lamina cribrosa, optic nerve on its entire course and meningeal sheaths free of tumor.

ICD-9A Discrepancy		
Tumor Malignancy History		
Qual/Synchron. vs Primary Noted		

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	40% epithelioid cells 60% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% epithelioid cells 1-30% spindle cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 79eed194-d5a7-43c6-bd07-fc35da6ffd31 (TCGA-V4-A9EW.7C41C1C2-D937-4DFC-9A8D-5E2944A7CC71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).